Somatic mutation profile of tumor specimen ALCH-B4EY-TTP1-A (aliquot ALCH-B4EY-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4EY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 62.7 years (22,911 days).
Specimen ALCH-B4EY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33d11f88-0376-4fc3-bdf1-107b579bfc4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4EY-NB1-A (Blood Derived Normal), aliquot ALCH-B4EY-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01ea1b81-743e-4974-aa62-03870de3fa2c

The open-access MAF lists 235 somatic variants for this specimen: 171 protein-altering or splice-affecting, 39 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 146, Silent 39, Intron 13, Nonsense Mutation 11, RNA 5, Splice Region 5, Splice Site 4, 3'UTR 3, Frame Shift Del 2, 5'Flank 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL9A3 | c.148-1G>A p.X50_splice | Splice Site (SNP) | VAF 51/796 reads (6%) | catalogued as rs606231367, CS000045; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 37/258 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4324G>A p.G1442S | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52636278; called by muse, mutect2, varscan2
- ABCA7 | c.3643G>T p.A1215S | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs757220996, COSV54038416; called by muse, mutect2, varscan2
- ABCC3 | c.1176+3C>T | Splice Region (SNP) | VAF 47/247 reads (19%) | catalogued as COSV53321435; called by muse, mutect2, varscan2
- ADAMTS18 | c.2969C>G p.A990G | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV51398535; called by muse, mutect2, varscan2
- AIPL1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1445697118; called by muse, mutect2, varscan2
- AKAP4 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV62074279; called by muse, varscan2
- AKAP6 | c.3181G>T p.A1061S | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV55212508; called by muse, mutect2, varscan2
- C6 | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.674); catalogued as COSV54718057; called by muse, mutect2, varscan2
- COL4A2 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 19/422 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.916); catalogued as rs975341170, COSV64632197; called by muse, mutect2
- DEPDC5 | c.2821G>T p.G941W (on ENST00000400246; = p.G1010W on NM_014662.5) | Missense Mutation (SNP) | VAF 57/556 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99836560; called by muse, mutect2, varscan2
- DGKB | c.358C>G p.R120G | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV99340130; called by muse, mutect2
- DIP2A | c.2645A>G p.D882G | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1389290924; called by muse, mutect2
- DNAH6 | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1382316616; called by muse, mutect2
- ELN | c.164C>A p.A55E | Missense Mutation (SNP) | VAF 105/918 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as CM060252; called by muse, mutect2, varscan2
- EPB41L3 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as COSV100548303; called by muse, mutect2
- FLI1 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55645173; called by muse, mutect2
- HPSE2 | c.772del p.E258Nfs*17 | Frame Shift Del (DEL) | VAF 28/318 reads (9%) | catalogued as COSV65203757; called by mutect2, pindel
- HTR5A | c.824G>C p.W275S | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV99840062; called by muse, mutect2
- IGHV1OR21-1 | c.86A>T p.E29V | Missense Mutation (SNP) | VAF 64/2266 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1486544105; called by muse, mutect2
- IGKV2D-29 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs748843940; called by muse, mutect2
- IL4I1 | c.107G>C p.C36S | Missense Mutation (SNP) | VAF 66/738 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62009721; called by muse, mutect2
- KCNQ1 | c.1642G>T p.G548C | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99328748; called by muse, mutect2, varscan2
- KIF19 | c.984T>G p.S328R | Missense Mutation (SNP) | VAF 63/357 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1225161458; called by muse, mutect2, varscan2
- KRAS | c.550A>T p.K184* | Nonsense Mutation (SNP) | VAF 28/358 reads (8%) | catalogued as rs749267065, COSV55587926; called by muse, mutect2
- LAMP5 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); catalogued as rs776246013, COSV55715926; called by muse, mutect2, varscan2
- LCE2A | c.246C>A p.H82Q | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); catalogued as COSV64226940; called by muse, mutect2, varscan2
- LGR5 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1036506346; called by muse, mutect2, varscan2
- MACF1 | c.2015C>G p.S672C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as rs1408558883; called by muse, mutect2
- MDGA1 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51791422; called by muse, mutect2
- MROH2B | c.3358G>A p.A1120T | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs780078430; called by muse, mutect2
- MS4A1 | c.337-3C>T | Splice Region (SNP) | VAF 10/160 reads (6%) | catalogued as COSV61941967; called by muse, mutect2
- MYH14 | c.3655G>A p.G1219S | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs200272339; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.2310C>T p.L770= | Splice Region (SNP) | VAF 6/62 reads (10%) | catalogued as COSV59142930; called by muse, mutect2
- MYPN | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 26/627 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62737364; called by muse, mutect2
- NOS2 | c.2320G>C p.G774R | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58222185; called by muse, mutect2
- NPHS1 | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 62/650 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.218); catalogued as rs868576714; called by muse, mutect2
- OR5B12 | c.162C>A p.H54Q | Missense Mutation (SNP) | VAF 35/432 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV56903904; called by muse, mutect2
- OR5D13 | c.700A>G p.S234G | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV62333603, COSV62334315; called by muse, mutect2
- OR7G3 | c.764G>C p.G255A | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV59640343; called by muse, mutect2
- PAPOLB | c.975C>G p.N325K | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68201067; called by muse, mutect2
- PCDHA10 | c.1186C>A p.L396M | Missense Mutation (SNP) | VAF 71/471 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs781784109; called by muse, mutect2, varscan2
- PCTP | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 55/336 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs1341431743; called by muse, mutect2, varscan2
- PUDP | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 70/556 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs200357826; called by muse, mutect2, varscan2
- RRBP1 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 24/363 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs200194432; called by muse, mutect2
- SERPINB2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs527405738, COSV99449478; called by muse, mutect2
- SND1 | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV61244559; called by muse, mutect2
- TLE1 | c.372+8G>T | Splice Region (SNP) | VAF 51/269 reads (19%) | catalogued as rs1253940816; called by muse, mutect2, varscan2
- TRPM1 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 72/630 reads (11%) | catalogued as COSV56634624, COSV56636990; called by muse, mutect2, varscan2
- TSC1 | c.1429A>T p.K477* | Nonsense Mutation (SNP) | VAF 79/526 reads (15%) | catalogued as COSV100052834, COSV53770915; called by muse, mutect2, varscan2
- TTLL2 | c.1340T>C p.L447P | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.271); catalogued as rs564037496; called by muse, mutect2
- TTN | c.93069C>A p.H31023Q (on ENST00000591111; = p.H23599Q on NM_003319.4) | Missense Mutation (SNP) | VAF 20/160 reads (13%) | PolyPhen probably damaging (0.996); catalogued as rs794729549; ClinVar: uncertain significance; called by muse, mutect2
- UNC13C | c.5984G>T p.G1995V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs975096476; called by muse, mutect2, varscan2
- ZNF280A | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 32/462 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.196); catalogued as rs1468242323, COSV100131195; called by muse, mutect2
- ZNF479 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 24/600 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58639037; called by muse, mutect2
- ZNF486 | c.461T>G p.F154C | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs1555718130; called by muse, mutect2
- ZNF496 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 166/839 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54173282, COSV54179476; called by muse, mutect2, varscan2
- ZNF853 | c.1860C>G p.H620Q | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as COSV71923077; called by muse, mutect2, varscan2
- A2M | c.1219T>A p.F407I | Missense Mutation (SNP) | VAF 36/509 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.339); called by muse, mutect2
- AC007040.2 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2
- ACOT11 | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 44/411 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRF5 | c.464A>T p.K155I | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); called by muse, mutect2
- ALAS2 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2
- ANKRD30A | c.1636T>A p.L546M (on ENST00000611781; = p.L490M on NM_052997.2) | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AP002512.3 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- APOBEC3G | c.538A>G p.K180E | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.88); called by muse, mutect2
- ARHGAP5 | c.848_849del p.V283Efs*11 | Frame Shift Del (DEL) | VAF 29/260 reads (11%) | called by pindel, varscan2
- ARHGEF9 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 43/406 reads (11%) | called by muse, mutect2, varscan2
- ARID1A | c.6479A>G p.N2160S | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.136); called by muse, mutect2
- ARSF | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 46/780 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by muse, mutect2
- ASIC5 | c.483C>G p.H161Q | Missense Mutation (SNP) | VAF 46/529 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2
- ASPM | c.3391-1G>T p.X1131_splice | Splice Site (SNP) | VAF 52/557 reads (9%) | called by muse, mutect2
- ATRN | c.2487G>T p.Q829H | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2
- BCORL1 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 62/418 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- C7 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 64/459 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C7 | c.1104C>A p.N368K | Missense Mutation (SNP) | VAF 40/415 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CAMK1G | c.307G>T p.G103W | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CASP5 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 68/698 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CCKAR | c.674T>C p.M225T | Missense Mutation (SNP) | VAF 314/1850 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CHAC1 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 60/644 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- CHRND | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 44/774 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- DAB2 | c.1861C>A p.Q621K | Missense Mutation (SNP) | VAF 40/400 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.391); called by muse, varscan2
- DDX51 | c.1333G>T p.G445C | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- DIPK2B | c.1250A>G p.D417G | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- DKK1 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMXL2 | c.8695C>T p.H2899Y | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DNAH2 | c.7796T>A p.V2599E | Missense Mutation (SNP) | VAF 46/373 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- EFCAB8 | c.2690G>T p.G897V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- ELF5 | c.586G>T p.E196* (on ENST00000312319 / NM_198381.2; = p.E186* on NM_001422.4) | Nonsense Mutation (SNP) | VAF 34/668 reads (5%) | called by muse, mutect2
- F5 | c.2189T>G p.L730R | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- FHL5 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- FIGNL1 | c.572C>G p.P191R | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2
- FSTL4 | c.1503C>G p.C501W | Missense Mutation (SNP) | VAF 57/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FTSJ1 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GATA1 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- GOLIM4 | c.850_857delinsTC p.R284_N286delinsS | In Frame Del (DEL) | VAF 14/87 reads (16%) | called by pindel, varscan2*
- GRM8 | c.2511G>C p.K837N | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HDC | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 48/960 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- HEATR6 | c.1934A>T p.K645M | Missense Mutation (SNP) | VAF 85/356 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IFNA13 | c.386G>C p.R129T | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- IRX2 | c.431A>T p.K144M | Missense Mutation (SNP) | VAF 28/561 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITPK1 | c.1004T>A p.L335Q | Missense Mutation (SNP) | VAF 73/802 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- ITPRID1 | c.2738T>A p.L913* | Nonsense Mutation (SNP) | VAF 36/465 reads (8%) | called by muse, mutect2
- KRT7 | c.335T>G p.L112R | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRTAP13-2 | c.351C>A p.C117* | Nonsense Mutation (SNP) | VAF 37/398 reads (9%) | called by muse, mutect2
- KTN1 | c.3889A>G p.I1297V (on ENST00000395314 / NM_001271014.2; = p.I1240V on NM_004986.4) | Missense Mutation (SNP) | VAF 46/361 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- LMX1A | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 20/295 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LPA | c.5132G>A p.S1711N | Missense Mutation (SNP) | VAF 49/467 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- LSAMP | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MAGEB3 | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 21/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- MAP1S | c.2245A>T p.K749* | Nonsense Mutation (SNP) | VAF 30/296 reads (10%) | called by muse, mutect2, varscan2
- MAP7D3 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MORC1 | c.851C>A p.A284E | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MROH2A | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MS4A6A | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- MUC19 | c.1045G>T p.V349L | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.205); called by muse, mutect2
- MUC4 | c.11081C>A p.A3694D | Missense Mutation (SNP) | VAF 120/784 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); called by muse, varscan2
- MYH7 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 64/842 reads (8%) | called by muse, mutect2
- NONO | c.1157A>T p.Q386L | Missense Mutation (SNP) | VAF 45/556 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.775); called by muse, mutect2
- NUTM2B | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 63/1356 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.718); called by muse, mutect2
- OGFR | c.1329C>G p.C443W | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- OR10H4 | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 29/316 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2
- OR10J1 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 43/401 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- OR11H2 | c.818G>T p.G273V (on ENST00000556246; = p.G284V on NM_001197287.1) | Missense Mutation (SNP) | VAF 59/480 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- OR2G2 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 27/344 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); called by muse, mutect2
- OR4K5 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 53/381 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- OR51D1 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, varscan2
- OR5H1 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 92/432 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- OR6N1 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); called by muse, mutect2
- OR6P1 | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2
- OR8D1 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 41/494 reads (8%) | called by muse, mutect2
- PAX4 | c.361-2A>T p.X121_splice | Splice Site (SNP) | VAF 74/678 reads (11%) | called by muse, mutect2, varscan2
- PCDHA6 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA3 | c.2366A>G p.E789G | Missense Mutation (SNP) | VAF 75/633 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PDGFC | c.219G>T p.L73F | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2
- PREX1 | c.4660C>A p.P1554T | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- PRTG | c.1741C>A p.L581M | Missense Mutation (SNP) | VAF 70/770 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PSG1 | c.56T>A p.L19Q | Missense Mutation (SNP) | VAF 86/707 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASEF | c.1763A>G p.E588G | Missense Mutation (SNP) | VAF 57/415 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- RYR2 | c.11817G>T p.R3939S | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SEMA5B | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SH3TC2 | c.86C>G p.S29W | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- SIPA1L2 | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2
- SLC17A2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOX9 | c.260_261insT p.L88Afs*164 | Frame Shift Ins (INS) | VAF 97/469 reads (21%) | called by mutect2, pindel, varscan2
- SV2B | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 27/265 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAAR9 | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TAF1L | c.2935G>T p.G979C | Missense Mutation (SNP) | VAF 42/405 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBX3 | c.524A>C p.K175T | Missense Mutation (SNP) | VAF 44/1111 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM121 | c.280T>G p.F94V | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); called by muse, mutect2
- TRAPPC9 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 58/419 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRBV7-1 | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TRIM42 | c.952C>A p.H318N | Missense Mutation (SNP) | VAF 108/478 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM77 | c.1257C>A p.S419R | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- TRRAP | c.3335A>T p.E1112V | Missense Mutation (SNP) | VAF 20/347 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.074); called by muse, mutect2
- TSC22D1 | c.3121G>A p.A1041T (on ENST00000458659 / NM_183422.4; = p.A112T on NM_006022.4) | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2
- TSC22D1 | c.1958C>G p.A653G | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2
- TTN | c.93070C>A p.L31024I (on ENST00000591111; = p.L23600I on NM_003319.4) | Missense Mutation (SNP) | VAF 20/154 reads (13%) | PolyPhen possibly damaging (0.488); called by muse, mutect2
- TTN | c.91531T>C p.F30511L (on ENST00000591111; = p.F23087L on NM_003319.4) | Missense Mutation (SNP) | VAF 35/411 reads (9%) | PolyPhen benign (0.164); called by muse, mutect2
- TTN | c.35719C>A p.P11907T (on ENST00000591111; = p.P4483T on NM_003319.4) | Missense Mutation (SNP) | VAF 20/250 reads (8%) | PolyPhen benign (0.059); called by muse, mutect2
- TTN | c.30475G>A p.V10159I (on ENST00000591111; = p.V9232I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/158 reads (8%) | PolyPhen probably damaging (0.98); called by muse, mutect2
- UBAP2 | c.1270+1G>T p.X424_splice | Splice Site (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2
- UBN2 | c.2615T>C p.L872S | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- WDR72 | c.857+4G>T | Splice Region (SNP) | VAF 66/892 reads (7%) | called by muse, mutect2
- WIZ | c.4237A>T p.K1413* (on ENST00000673675 / NM_001371589.1; = p.K318* on NM_021241.3) | Nonsense Mutation (SNP) | VAF 24/645 reads (4%) | called by muse, mutect2
- WT1 | c.1406G>C p.C469S | Missense Mutation (SNP) | VAF 41/1380 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZBTB1 | c.839A>C p.Q280P | Missense Mutation (SNP) | VAF 48/331 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZDBF2 | c.4771C>A p.P1591T | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.053); called by muse, varscan2
- ZNF521 | c.2214G>T p.Q738H | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF700 | c.150G>T p.R50S | Missense Mutation (SNP) | VAF 41/453 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- AGXT | c.786C>T p.H262= | Silent (SNP) | VAF 28/461 reads (6%) | called by muse, mutect2
- B4GALNT1 | c.1090C>A p.R364= | Silent (SNP) | VAF 41/370 reads (11%) | catalogued as COSV57545379; called by muse, mutect2, varscan2
- BSPRY | c.1053A>T p.P351= | Silent (SNP) | VAF 31/177 reads (18%) | called by muse, mutect2, varscan2
- C22orf42 | c.243C>A p.A81= | Silent (SNP) | VAF 36/437 reads (8%) | called by muse, mutect2
- C3orf22 | c.51C>A p.I17= | Silent (SNP) | VAF 42/456 reads (9%) | called by muse, mutect2
- CAMTA1 | c.1554G>C p.G518= | Silent (SNP) | VAF 21/369 reads (6%) | called by muse, mutect2
- CIC | c.3414G>C p.P1138= | Silent (SNP) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- CR2 | c.3060A>G p.A1020= | Silent (SNP) | VAF 33/476 reads (7%) | called by muse, mutect2
- DNAH5 | c.11808A>G p.K3936= | Silent (SNP) | VAF 30/353 reads (8%) | called by muse, mutect2
- FAM89B | c.420G>T p.S140= (on ENST00000530349 / NM_001098785.2; = p.S127= on NM_152832.3) | Silent (SNP) | VAF 19/352 reads (5%) | called by muse, mutect2
- GRIPAP1 | c.2017C>A p.R673= | Silent (SNP) | VAF 16/418 reads (4%) | called by muse, mutect2
- HIC1 | c.1086C>T p.D362= (on ENST00000322941 / NM_001098202.1; = p.D343= on NM_006497.4) | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as rs945656864; called by muse, mutect2, varscan2
- IFNA13 | c.228A>T p.P76= | Silent (SNP) | VAF 23/375 reads (6%) | called by muse, mutect2, varscan2
- IGF2R | c.6300G>T p.V2100= | Silent (SNP) | VAF 46/436 reads (11%) | catalogued as COSV100807343; called by muse, mutect2, varscan2
- IGKV2D-29 | c.117C>A p.A39= | Silent (SNP) | VAF 18/299 reads (6%) | called by muse, mutect2
- ITPK1 | c.1005G>T p.L335= | Silent (SNP) | VAF 72/790 reads (9%) | called by muse, mutect2
- ITPR3 | c.2661A>T p.T887= | Silent (SNP) | VAF 28/457 reads (6%) | called by muse, mutect2
- KLHL34 | c.204C>A p.R68= | Silent (SNP) | VAF 30/170 reads (18%) | catalogued as rs1389082426, COSV101069890; called by muse, mutect2, varscan2
- MAP3K12 | c.132T>C p.P44= | Silent (SNP) | VAF 16/374 reads (4%) | catalogued as COSV57231600; called by muse, mutect2
- MARCO | c.327T>A p.G109= | Silent (SNP) | VAF 20/584 reads (3%) | called by muse, mutect2
- MLXIPL | c.2154G>T p.R718= | Silent (SNP) | VAF 31/514 reads (6%) | catalogued as COSV57668353; called by muse, mutect2
- MTTP | c.1224G>T p.L408= | Silent (SNP) | VAF 20/375 reads (5%) | called by muse, mutect2
- MYH8 | c.3396A>G p.R1132= | Silent (SNP) | VAF 26/391 reads (7%) | catalogued as COSV67966087; called by muse, mutect2
- MYO3A | c.2907G>T p.L969= | Silent (SNP) | VAF 66/662 reads (10%) | called by muse, mutect2, varscan2
- OCA2 | c.555C>A p.A185= | Silent (SNP) | VAF 54/1079 reads (5%) | catalogued as COSV100667041; called by muse, mutect2
- OR10J1 | c.588C>A p.I196= | Silent (SNP) | VAF 44/401 reads (11%) | catalogued as COSV71129372; called by muse, mutect2, varscan2
- OR4K5 | c.159C>G p.T53= | Silent (SNP) | VAF 36/292 reads (12%) | called by muse, mutect2, varscan2
- PCDHA6 | c.1557G>A p.A519= | Silent (SNP) | VAF 58/831 reads (7%) | catalogued as COSV65341794; called by muse, mutect2
- PCDHGB6 | c.1098T>C p.V366= | Silent (SNP) | VAF 13/215 reads (6%) | called by muse, mutect2
- PHACTR3 | c.477C>A p.A159= | Silent (SNP) | VAF 48/491 reads (10%) | called by muse, mutect2
- SASH1 | c.1614C>T p.S538= | Silent (SNP) | VAF 37/345 reads (11%) | catalogued as rs758062867; called by muse, mutect2, varscan2
- SDSL | c.675G>A p.V225= | Silent (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- SLC39A6 | c.1605G>T p.G535= | Silent (SNP) | VAF 38/446 reads (9%) | called by muse, mutect2
- SPATA31A6 | c.1659T>G p.A553= | Silent (SNP) | VAF 38/1141 reads (3%) | called by muse, mutect2
- SPTA1 | c.3786A>G p.R1262= | Silent (SNP) | VAF 52/612 reads (8%) | called by muse, mutect2
- STYXL2 | c.2118C>A p.P706= | Silent (SNP) | VAF 20/154 reads (13%) | catalogued as COSV99608367; called by muse, mutect2, varscan2
- TMEM131 | c.1350T>C p.D450= | Silent (SNP) | VAF 28/432 reads (6%) | called by muse, mutect2
- ZFHX4 | c.6240C>A p.S2080= | Silent (SNP) | VAF 14/338 reads (4%) | catalogued as COSV51483245; called by muse, mutect2
- ZNF735 | c.21C>T p.P7= | Silent (SNP) | VAF 34/696 reads (5%) | catalogued as COSV70036155; called by muse, mutect2
- AC012236.1 | n.455-66C>A | Intron (SNP) | VAF 30/489 reads (6%) | called by muse, mutect2
- AC097518.1 | n.302C>T | RNA (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- AOC4P | n.1450A>T | RNA (SNP) | VAF 131/571 reads (23%) | called by muse, varscan2
- ASTN2 | c.3782+3264G>A | Intron (SNP) | VAF 48/365 reads (13%) | called by muse, mutect2, varscan2
- BDH2 | c.249-433G>C | Intron (SNP) | VAF 46/608 reads (8%) | called by muse, mutect2
- CAPN2 | c.*9C>T | 3'UTR (SNP) | VAF 42/459 reads (9%) | called by muse, mutect2
- CCT3 | c.31+1001A>G | Intron (SNP) | VAF 16/216 reads (7%) | catalogued as rs1291738365; called by muse, mutect2
- EYS | c.1767-6729T>C | Intron (SNP) | VAF 63/687 reads (9%) | called by muse, mutect2, varscan2
- FAM183BP | n.1031A>T | RNA (SNP) | VAF 38/612 reads (6%) | called by muse, mutect2
- FILIP1L | c.605+25650T>C | Intron (SNP) | VAF 30/96 reads (31%) | called by muse, varscan2
- HOATZ | chr11:111513474 T>C | 5'Flank (SNP) | VAF 18/342 reads (5%) | called by muse, mutect2
- KLHL4 | c.*7C>A | 3'UTR (SNP) | VAF 27/239 reads (11%) | called by muse, mutect2, varscan2
- L3HYPDH | c.508+37G>A | Intron (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- LINC01193 | n.783G>T | RNA (SNP) | VAF 32/375 reads (9%) | called by muse, mutect2
- MACF1 | c.220+18461C>T | Intron (SNP) | VAF 52/878 reads (6%) | called by muse, mutect2
- MIR1270 | chr19:20397362 T>C | 3'Flank (SNP) | VAF 46/584 reads (8%) | catalogued as rs944402086; called by muse, mutect2
- PAX8 | c.1189+53C>A | Intron (SNP) | VAF 30/555 reads (5%) | called by muse, mutect2
- PCP4L1 | c.-11C>T | 5'UTR (SNP) | VAF 40/391 reads (10%) | catalogued as rs1429366123; called by muse, mutect2
- PDE1C | c.980+33C>A | Intron (SNP) | VAF 40/415 reads (10%) | called by muse, mutect2
- PPME1 | c.346+310G>T | Intron (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2
- RNU6-713P | chr12:40558130 A>G | 5'Flank (SNP) | VAF 58/572 reads (10%) | called by muse, mutect2
- RPGR | c.2520+1467C>A | Intron (SNP) | VAF 52/852 reads (6%) | called by muse, mutect2
- SEC1P | n.498C>G | RNA (SNP) | VAF 56/510 reads (11%) | called by muse, mutect2, varscan2
- SPATA20 | c.946-34G>A | Intron (SNP) | VAF 42/152 reads (28%) | called by muse, mutect2, varscan2
- UQCRB | c.*1302G>C | 3'UTR (SNP) | VAF 59/564 reads (10%) | called by muse, mutect2, varscan2
